Somatic mutation profile of tumor specimen TCGA-AA-3977-01A (aliquot TCGA-AA-3977-01A-01W-0995-10) from TCGA case TCGA-AA-3977, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 65.2 years (23,832 days).
Specimen TCGA-AA-3977-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba12a9a2-2621-42a4-b8f9-6672e3315c38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3977-10A (Blood Derived Normal), aliquot TCGA-AA-3977-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d61a57b6-3c0a-4bf1-a483-da3ebb4e3a3e

The open-access MAF lists 3,916 somatic variants for this specimen: 3,114 protein-altering or splice-affecting, 721 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,673, Silent 721, Nonsense Mutation 373, Intron 38, Splice Site 34, RNA 26, Splice Region 18, 3'UTR 8, Frame Shift Ins 6, Frame Shift Del 5, 3'Flank 4, Translation Start Site 3.

Variants (750 of 3,916; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as rs797044676, CM010174, COSV59903636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLN5 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 35/147 reads (24%) | catalogued as rs386833971, CM120887, COSV66285061; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.1255C>T p.R419* (on ENST00000676605; = p.R378* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as rs374703898, CM140106, COSV51580938; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MED12 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 20/32 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199469669, COSV61329437, COSV61329567, COSV61330093; ClinVar: not provided; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>T p.M1043I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 21/99 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV100692084, COSV61005894; called by muse, mutect2, varscan2
- RARB | c.1180C>T p.R394C (on ENST00000383772 / NM_001290216.2; = p.R387C on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397518483, CM139363, CM139364, COSV51978266; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1760G>A p.R587Q (on ENST00000373993 / NM_138932.2; = p.R579Q on NM_014576.4) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); catalogued as rs530902814, COSV50965034; called by muse, mutect2, varscan2
- A1CF | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as rs772118222, COSV50957228; called by muse, mutect2, varscan2
- AACS | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV99907705; called by muse, mutect2, varscan2
- AASDH | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1217671487, COSV52711119; called by muse, mutect2, varscan2
- AASS | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100741642, COSV100741808; called by muse, mutect2, varscan2
- ABCA1 | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101035491; called by muse, mutect2, varscan2
- ABCA12 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs1283642196, COSV55954325, COSV99788064, COSV99791861; called by muse, mutect2, varscan2
- ABCA13 | c.4769T>C p.V1590A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV70031327; called by muse, mutect2, varscan2
- ABCA13 | c.6427G>T p.E2143* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV101329905; called by muse, mutect2, varscan2
- ABCA13 | c.8525G>T p.R2842I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV71286080, COSV71288716; called by muse, varscan2
- ABCA13 | c.10903G>A p.V3635I | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570952854, COSV101446729; called by muse, mutect2, varscan2
- ABCA13 | c.11291G>T p.S3764I | Missense Mutation (SNP) | VAF 46/666 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV101446730; called by muse, mutect2
- ABCA13 | c.14476C>T p.R4826C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs200851445; called by muse, mutect2, varscan2
- ABCA3 | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.196); catalogued as COSV100067953; called by muse, mutect2, varscan2
- ABCA4 | c.6541G>T p.D2181Y | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100933013; called by muse, mutect2
- ABCA4 | c.4641G>T p.K1547N | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV100933014; called by muse, mutect2
- ABCA4 | c.4552A>C p.S1518R | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as CM1311031, COSV100933015; called by muse, mutect2
- ABCA4 | c.1923C>A p.C641* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100933016; called by muse, mutect2, varscan2
- ABCA5 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs753649836, COSV101200961; called by muse, mutect2
- ABCA5 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 44/171 reads (26%) | catalogued as COSV101200963; called by muse, mutect2, varscan2
- ABCA5 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101200965; called by muse, mutect2, varscan2
- ABCA6 | c.1307A>C p.N436T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV99445694; called by muse, mutect2, varscan2
- ABCA8 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs768333090, COSV52197981; called by muse, mutect2, varscan2
- ABCA9 | c.4735G>A p.D1579N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1455091157, COSV100382553; called by muse, mutect2, varscan2
- ABCA9 | c.4482G>T p.M1494I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.362); catalogued as COSV100382554; called by muse, mutect2, varscan2
- ABCA9 | c.3687G>T p.K1229N | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100382555; called by muse, mutect2, varscan2
- ABCA9 | c.3260T>A p.I1087K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as COSV100382557; called by muse, mutect2, varscan2
- ABCB1 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 155/622 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99712004; called by muse, mutect2, varscan2
- ABCB11 | c.3113C>T p.T1038I | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99791466; called by muse, mutect2, varscan2
- ABCB11 | c.1738C>A p.L580M | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99791472; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCC12 | c.1786-1G>T p.X596_splice | Splice Site (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100252102; called by muse, mutect2
- ABCC5 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 447/1449 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99656322; called by muse, mutect2, varscan2
- ABCC8 | c.2553C>A p.F851L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100216531, COSV56848229; called by muse, mutect2, varscan2
- ABCD2 | c.991A>T p.N331Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100429115; called by muse, varscan2
- ABCD2 | c.701A>G p.D234G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429118, COSV58050699; called by muse, mutect2, varscan2
- ABCG2 | c.21A>C p.E7D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs747453638, COSV99418377; called by muse, mutect2, varscan2
- ABHD3 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100004176; called by muse, mutect2, varscan2
- ABHD3 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100004179; called by muse, mutect2, varscan2
- ABHD6 | c.419A>C p.K140T | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV99916869; called by muse, mutect2
- ABI1 | c.1265A>C p.E422A | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV100697697; called by muse, mutect2, varscan2
- ABI3BP | c.1996C>T p.H666Y | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99425178; called by muse, mutect2, varscan2
- ABTB2 | c.2484G>T p.K828N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as rs749055024, COSV100130572; called by muse, mutect2, varscan2
- AC090517.4 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as rs995380074, COSV99974019; called by muse, mutect2, varscan2
- AC245748.1 | c.16-1G>T p.X6_splice | Splice Site (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100495441; called by muse, mutect2, varscan2
- ACACA | c.7118G>A p.R2373Q | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs773877053; called by muse, mutect2
- ACACB | c.2476C>A p.L826I | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV100622246; called by muse, mutect2, varscan2
- ACADSB | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100715061; called by muse, varscan2
- ACBD5 | c.1051C>T p.R351C (on ENST00000375888 / NM_001352568.1; = p.R342C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755306488, COSV65517960; called by muse, mutect2, varscan2
- ACE2 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs865959788, COSV99382506; called by muse, mutect2, varscan2
- ACER1 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); catalogued as COSV100033918; called by muse, mutect2, varscan2
- ACIN1 | c.3841C>T p.R1281W | Missense Mutation (SNP) | VAF 232/660 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99398963; called by muse, varscan2
- ACO2 | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV99346954; called by muse, mutect2, varscan2
- ACOT11 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as rs377475734; called by muse, mutect2, varscan2
- ACOT12 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100296695; called by muse, mutect2, varscan2
- ACOT2 | c.26A>G p.H9R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99468736; called by muse, mutect2
- ACP3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs777654881, COSV60484679; called by muse, mutect2, varscan2
- ACP5 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs922892618, COSV99520165, COSV99520252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSL3 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1177812495, COSV62483596, COSV62485156; called by muse, mutect2, varscan2
- ACSL4 | c.1960C>T p.R654* (on ENST00000340800 / NM_022977.2; = p.R613* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as CM151038, COSV100538347, COSV61614626; called by muse, mutect2, varscan2
- ACSL5 | c.1078G>T p.D360Y (on ENST00000354273; = p.D416Y on NM_016234.3) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100634450, COSV100634463; called by muse, mutect2, varscan2
- ACTBL2 | c.1026T>G p.I342M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV101379218; called by muse, varscan2
- ACTRT1 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64418954, COSV64420046; called by muse, mutect2, varscan2
- ADAM17 | c.1891A>G p.T631A | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100176001; called by muse, mutect2, varscan2
- ADAM21 | c.1190C>A p.P397H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV99960428; called by muse, mutect2, varscan2
- ADAM21 | c.1790T>C p.L597S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV99960433; called by muse, mutect2, varscan2
- ADAM23 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs768532736, COSV52211455; called by mutect2, varscan2
- ADAM29 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV63669214; called by muse, mutect2, varscan2
- ADAM30 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs781229975, COSV65560969; called by muse, mutect2, varscan2
- ADAM9 | c.1856A>G p.E619G | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV101165956; called by muse, mutect2
- ADAMDEC1 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753833406, COSV56474653, COSV99835826; called by muse, varscan2
- ADAMTS14 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV100941321; called by muse, mutect2, varscan2
- ADAMTS14 | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1212996063, COSV64604450; called by muse, mutect2, varscan2
- ADAMTS16 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754295364, COSV57009975; called by muse, mutect2, varscan2
- ADAMTS16 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV57007015; called by muse, mutect2, varscan2
- ADAMTS18 | c.1106G>A p.C369Y | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99271012; called by muse, mutect2, varscan2
- ADAMTS18 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs891093965, COSV51399337; called by mutect2, varscan2
- ADAMTS18 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV51418267, COSV99271018; called by muse, mutect2
- ADAMTS2 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs201702236; called by muse, mutect2, varscan2
- ADAMTS3 | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.12); catalogued as rs958050802, COSV99710072; called by muse, mutect2, varscan2
- ADAMTS3 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 84/334 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV99710074; called by muse, mutect2, varscan2
- ADAMTS9 | c.4166G>A p.G1389D | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757408086, COSV99898613; called by muse, mutect2, varscan2
- ADAMTSL1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); catalogued as COSV52816905, COSV99440721; called by muse, varscan2
- ADAMTSL1 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV101001203; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1002C>A p.F334L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.294); catalogued as COSV54472187, COSV99716713; called by muse, mutect2, varscan2
- ADAR | c.3657G>T p.K1219N | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52713651; called by muse, mutect2, varscan2
- ADAT2 | c.572C>A p.S191Y | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99395582; called by muse, mutect2, varscan2
- ADCY2 | c.1006A>T p.I336F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100601640; called by muse, mutect2, varscan2
- ADCY2 | c.2362T>C p.Y788H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100601641; called by muse, mutect2, varscan2
- ADCY8 | c.3487G>T p.G1163* | Nonsense Mutation (SNP) | VAF 37/163 reads (23%) | catalogued as COSV53901919, COSV99650540; called by muse, mutect2, varscan2
- ADCY9 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs772697228, COSV53574136; called by mutect2, varscan2
- ADCYAP1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as rs1487295797, COSV52487224; called by muse, mutect2, varscan2
- ADGRB3 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100999632; called by muse, varscan2
- ADGRD1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761685448, COSV55460845; called by muse, mutect2, varscan2
- ADGRE1 | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99165008; called by muse, mutect2, varscan2
- ADGRE1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 65/175 reads (37%) | catalogued as COSV51671532, COSV51672387; called by muse, mutect2, varscan2
- ADGRG4 | c.3917A>C p.K1306T | Missense Mutation (SNP) | VAF 71/108 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99794219; called by muse, mutect2, varscan2
- ADGRG4 | c.7887C>A p.F2629L | Missense Mutation (SNP) | VAF 109/206 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1334865153, COSV99794222; called by muse, mutect2, varscan2
- ADGRG4 | c.9090G>T p.K3030N | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV54963432, COSV99794228; called by muse, mutect2, varscan2
- ADGRL2 | c.3118G>A p.A1040T (on ENST00000370717 / NM_001366005.1; = p.A1027T on NM_012302.4) | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1470284505, COSV54663803, COSV54665192; called by muse, mutect2, varscan2
- ADGRL3 | c.1717G>T p.E573* (on ENST00000506720 / NM_001322402.2; = p.E505* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV72232225; called by muse, mutect2, varscan2
- ADGRL3 | c.3752G>A p.R1251Q (on ENST00000506720 / NM_001322402.2; = p.R1183Q on NM_015236.6) | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189094336, COSV72229226; called by muse, mutect2, varscan2
- ADGRV1 | c.8124G>T p.Q2708H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV101315411; called by muse, mutect2, varscan2
- ADGRV1 | c.9071A>G p.Y3024C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV67979166; called by muse, mutect2, varscan2
- ADH5 | c.305T>G p.F102C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99596085; called by muse, mutect2, varscan2
- ADIPOQ | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs777244635, COSV100292068; called by muse, mutect2, varscan2
- ADRA1B | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs1330843392, COSV100140049; called by muse, mutect2, varscan2
- AFDN | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as rs1200053221; called by muse, mutect2
- AFF1 | c.1025C>A p.S342Y | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV57125539; called by muse, mutect2, varscan2
- AFF3 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.361); catalogued as COSV100417480, COSV57840534; called by muse, mutect2, varscan2
- AFP | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99889638; called by muse, mutect2, varscan2
- AFP | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV99889641; called by muse, mutect2, varscan2
- AFTPH | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99480261; called by muse, mutect2, varscan2
- AGAP1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs777883161, COSV58327760; called by muse, varscan2
- AGAP2 | c.1655G>A p.G552E (on ENST00000547588 / NM_001122772.2; = p.G216E on NM_014770.4) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99222135; called by muse, mutect2, varscan2
- AGBL1 | c.1100A>C p.K367T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV101222162; called by muse, mutect2, varscan2
- AGL | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs375531470; called by muse, mutect2, varscan2
- AHCTF1 | c.1229C>T p.S410L (on ENST00000366508; = p.S384L on NM_015446.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58246164; called by muse, mutect2, varscan2
- AHCTF1 | c.730C>T p.R244C (on ENST00000366508; = p.R218C on NM_015446.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753602111, COSV58254928; called by muse, mutect2, varscan2
- AHCYL2 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100272823; called by muse, mutect2, varscan2
- AHSG | c.685T>G p.F229V | Missense Mutation (SNP) | VAF 25/477 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99889811; called by muse, mutect2
- AIFM3 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV59005300; called by muse, mutect2, varscan2
- AK8 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.369); catalogued as rs750120409, COSV53754113; called by muse, mutect2, varscan2
- AKAP12 | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs368517285; called by muse, mutect2, varscan2
- AKAP3 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99961729; called by muse, mutect2, varscan2
- AKAP6 | c.2354T>C p.V785A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99797939; called by muse, mutect2, varscan2
- AKAP6 | c.3330G>T p.K1110N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV99797944; called by muse, mutect2, varscan2
- AKAP6 | c.6104A>G p.N2035S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99797948; called by muse, mutect2, varscan2
- AKAP9 | c.11206C>T p.R3736* (on ENST00000359028; = p.R3712* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | catalogued as rs1234676587, COSV62354774; called by muse, mutect2
- AL592490.1 | c.2179A>C p.K727Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV69428336; called by muse, mutect2, varscan2
- ALAS1 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100050187; called by muse, mutect2, varscan2
- ALDH1A1 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 152/441 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920986; called by muse, mutect2, varscan2
- ALDH1A3 | c.376T>A p.F126I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100320220; called by muse, mutect2
- ALDH1L1 | c.1041C>A p.F347L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1048277457, COSV99856448; called by muse, mutect2, varscan2
- ALDH8A1 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV99664387; called by muse, mutect2, varscan2
- ALG10 | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99847882; called by muse, mutect2, varscan2
- ALK | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as rs1267142388, COSV101201064; called by muse, mutect2, varscan2
- ALKBH2 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as COSV99655166; called by muse, mutect2, varscan2
- ALMS1 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as rs759021934, COSV100040985; called by muse, mutect2, varscan2
- ALMS1 | c.6269C>A p.S2090Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV100040987; called by muse, varscan2
- ALOX15B | c.711C>A p.F237L | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV101205561; called by muse, mutect2, varscan2
- ALOX15B | c.1354T>G p.S452A | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV101205563; called by muse, mutect2
- ALOX5 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100979934; called by muse, mutect2, varscan2
- ALPK1 | c.2870C>A p.S957Y | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51584459, COSV99452703; called by muse, mutect2, varscan2
- ALPK2 | c.5250G>T p.K1750N | Missense Mutation (SNP) | VAF 88/308 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV64491095; called by muse, varscan2
- ALS2 | c.4849T>G p.L1617V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99968659; called by muse, mutect2
- AMER1 | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs758807218, COSV100365211; called by muse, mutect2
- AMMECR1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 100/168 reads (60%) | catalogued as COSV99466195; called by muse, mutect2, varscan2
- AMPD3 | c.716A>G p.E239G (on ENST00000396553 / NM_001025389.2; = p.E248G on NM_000480.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101158072; called by muse, mutect2, varscan2
- AMZ2 | c.684C>A p.D228E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV100703080; called by muse, mutect2, varscan2
- ANAPC1 | c.1286A>C p.K429T | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100594489; called by muse, mutect2, varscan2
- ANAPC15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs982888986, COSV56191427; called by muse, mutect2
- ANGPTL1 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.15); catalogued as COSV52366100; called by muse, mutect2, varscan2
- ANGPTL5 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs758888750, COSV100527609; called by muse, mutect2, varscan2
- ANK1 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs769707255, COSV99223750; called by muse, mutect2, varscan2
- ANK2 | c.9985T>G p.F3329V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV99999330; called by muse, mutect2, varscan2
- ANK3 | c.6902C>A p.S2301Y | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV99778088; called by muse, mutect2, varscan2
- ANK3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55065523; called by muse, mutect2, varscan2
- ANKH | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99414404; called by muse, mutect2, varscan2
- ANKMY2 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100186835; called by muse, mutect2, varscan2
- ANKRD1 | c.796A>G p.K266E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs759544911, COSV100865277; called by muse, mutect2, varscan2
- ANKRD13A | c.148T>C p.S50P | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99923819; called by muse, mutect2, varscan2
- ANKRD17 | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV100428468; called by muse, mutect2, varscan2
- ANKRD26 | c.4703C>A p.S1568Y | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101062889; called by muse, mutect2, varscan2
- ANKRD26 | c.3512T>G p.F1171C | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV101062891; called by muse, mutect2, varscan2
- ANKRD30A | c.715G>T p.V239L (on ENST00000611781; = p.V183L on NM_052997.2) | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100652817; called by muse, varscan2
- ANKRD44 | c.2436-1G>T p.X812_splice | Splice Site (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99983921; called by muse, mutect2, varscan2
- ANKRD50 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV101538877, COSV72385130; called by muse, mutect2, varscan2
- ANKRD50 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs763266709, COSV72385175; called by muse, mutect2, varscan2
- ANKRD7 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99500895; called by muse, mutect2, varscan2
- ANKS1B | c.1814T>G p.F605C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61382000; called by muse, mutect2, varscan2
- ANKS6 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1221413415, COSV62051210; called by muse, mutect2, varscan2
- ANKZF1 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1334953246, COSV55477330; called by muse, mutect2, varscan2
- ANO4 | c.397G>T p.E133* (on ENST00000392977 / NM_001286615.2; = p.E98* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100151725; called by muse, mutect2, varscan2
- ANO4 | c.2807T>C p.L936P (on ENST00000392977 / NM_001286615.2; = p.L901P on NM_178826.4) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100151726; called by muse, mutect2, varscan2
- ANPEP | c.2132G>A p.R711H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); catalogued as rs182672249; called by muse, mutect2, varscan2
- ANXA2 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs753106303, COSV100221852; called by muse, mutect2, varscan2
- ANXA4 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.782); catalogued as COSV101268756; called by muse, mutect2, varscan2
- AOC3 | c.945G>T p.Q315H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.228); catalogued as COSV99519913; called by muse, mutect2, varscan2
- AOC3 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99519917; called by muse, varscan2
- AOX1 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99613342; called by muse, mutect2, varscan2
- AP1AR | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs367798505; called by muse, mutect2, varscan2
- AP1G2 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as COSV99846050; called by muse, mutect2, varscan2
- AP3B1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474612691, COSV99670589, COSV99671381; called by muse, mutect2, varscan2
- AP4B1 | c.947A>C p.K316T | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99870502; called by muse, mutect2, varscan2
- AP5M1 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs368987446; called by muse, mutect2, varscan2
- APAF1 | c.2339G>T p.S780I (on ENST00000551964 / NM_181861.2; = p.S769I on NM_001160.3) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100452254; called by muse, mutect2, varscan2
- APAF1 | c.2595G>A p.E865= (on ENST00000551964 / NM_181861.2; = p.E854= on NM_013229.3) | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as rs1480823721, COSV100452255; called by muse, mutect2, varscan2
- APC | c.5518T>G p.F1840V | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV99964922; called by muse, mutect2
- APC | c.6086C>A p.S2029Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99964923, COSV99964952; called by muse, mutect2, varscan2
- APCDD1 | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs149564774; called by muse, mutect2, varscan2
- APCDD1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.576); catalogued as rs771909445, COSV62372830; called by mutect2, varscan2
- APH1B | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); catalogued as rs748873773; called by muse, mutect2, varscan2
- APLP1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV99697450; called by muse, mutect2
- APLP1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as rs763547342, COSV55702120; called by muse, mutect2, varscan2
- APMAP | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99468116; called by muse, mutect2, varscan2
- APOA2 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as COSV99248074; called by muse, mutect2, varscan2
- APOL3 | c.938G>A p.R313Q (on ENST00000349314 / NM_145640.2; = p.R242Q on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs773872410, COSV62580362; called by muse, mutect2, varscan2
- AQP3 | c.483C>A p.F161L | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99955472; called by muse, mutect2, varscan2
- AQR | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99333069; called by muse, mutect2, varscan2
- AR | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as rs750324117, CM035613, COSV65953437, COSV65963147; called by muse, mutect2, varscan2
- ARAP1 | c.2150G>A p.R717Q (on ENST00000393609 / NM_001040118.2; = p.R472Q on NM_015242.4) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as rs778301113, COSV100501502; called by muse, mutect2, varscan2
- ARAP2 | c.1280G>T p.R427I | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100394047, COSV58292047; called by muse, mutect2, varscan2
- ARCN1 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV50615041, COSV99873380; called by muse, mutect2, varscan2
- ARFGEF1 | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 36/146 reads (25%) | catalogued as COSV99141048, COSV99144661; called by muse, mutect2, varscan2
- ARFGEF2 | c.4828C>T p.H1610Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs995799318, COSV64213598; called by muse, mutect2, varscan2
- ARFGEF3 | c.2584C>T p.R862C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759459619, COSV99292157; called by muse, mutect2, varscan2
- ARHGAP11A | c.2453C>A p.S818Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100276645; called by muse, mutect2, varscan2
- ARHGAP20 | c.3338C>A p.S1113Y | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52805929, COSV99503010; called by muse, mutect2
- ARHGAP21 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995838696, COSV100255684; called by muse, mutect2, varscan2
- ARHGAP22 | c.1938G>T p.K646N | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV50940567, COSV50970444; called by muse, mutect2, varscan2
- ARHGAP31 | c.881+1G>T p.X294_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99956474; called by muse, mutect2, varscan2
- ARHGAP31 | c.2211G>T p.E737D | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as COSV99956477; called by muse, mutect2, varscan2
- ARHGAP9 | c.1504C>T p.R502W (on ENST00000393797 / NM_001319850.2; = p.R483W on NM_032496.4) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV99953631; called by muse, mutect2, varscan2
- ARHGEF1 | c.99C>G p.N33K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100528831, COSV100529194; called by muse, mutect2, varscan2
- ARHGEF10 | c.3347C>T p.A1116V (on ENST00000398564; = p.A1091V on NM_014629.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs769153898, COSV100033639; called by muse, mutect2, varscan2
- ARHGEF26 | c.2115T>G p.D705E | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62852835; called by muse, mutect2, varscan2
- ARHGEF3 | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.013); catalogued as COSV99574856; called by muse, mutect2, varscan2
- ARHGEF3 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs776506559, COSV56324378; called by muse, mutect2, varscan2
- ARHGEF37 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs369500713; called by muse, mutect2, varscan2
- ARHGEF37 | c.2024C>A p.S675Y | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100381869; called by muse, mutect2
- ARHGEF4 | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as COSV100387518; called by muse, mutect2
- ARHGEF6 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 19/184 reads (10%) | catalogued as COSV51689165, COSV99166766; called by muse, mutect2, varscan2
- ARID1B | c.3250C>T p.P1084S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746686035, COSV99266836; called by muse, mutect2, varscan2
- ARID2 | c.1700T>G p.F567C | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100535307; called by muse, mutect2, varscan2
- ARID4A | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as rs375498932; called by muse, mutect2, varscan2
- ARL14 | c.210A>C p.K70N | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100296384; called by muse, mutect2
- ARL6IP5 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99832907; called by muse, mutect2, varscan2
- ARMC2 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100933444; called by muse, mutect2, varscan2
- ARMC3 | c.362-1G>T p.X121_splice | Splice Site (SNP) | VAF 101/330 reads (31%) | catalogued as COSV99957375; called by muse, mutect2, varscan2
- ARMC4 | c.2557G>T p.D853Y | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100536247; called by muse, mutect2, varscan2
- ARMC5 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51658619; called by muse, mutect2, varscan2
- ARMH4 | c.1629G>T p.M543I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99957523; called by muse, mutect2, varscan2
- ARMT1 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as rs560894715, COSV100939733; called by muse, mutect2, varscan2
- ARRDC3 | c.1009T>G p.L337V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99475139; called by muse, mutect2, varscan2
- ARRDC5 | c.487G>T p.E163* (on ENST00000381781; = p.E149* on NM_001080523.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/227 reads (18%) | catalogued as COSV101108073; called by muse, mutect2, varscan2
- ARSF | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs752507528, COSV63841509; called by mutect2, varscan2
- ARSJ | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756542116, COSV59537244; called by muse, mutect2, varscan2
- ARSL | c.1097A>G p.Q366R | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV101140381; called by muse, mutect2, varscan2
- ART3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.687); catalogued as rs776884042, COSV100587504; called by muse, mutect2, varscan2
- ASB5 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV99641189, COSV99641368; called by muse, mutect2, varscan2
- ASB5 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99641193; called by muse, mutect2, varscan2
- ASB5 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs370097719; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 35/113 reads (31%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASF1A | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as COSV99995709; called by muse, mutect2, varscan2
- ASH1L | c.7123C>T p.R2375C (on ENST00000368346 / NM_001366177.2; = p.R2370C on NM_018489.3) | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV64212393; called by muse, mutect2, varscan2
- ASH1L | c.6841C>T p.R2281* (on ENST00000368346 / NM_001366177.2; = p.R2276* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | catalogued as COSV64210367; called by muse, mutect2, varscan2
- ASH1L | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs746450493, COSV64210433; called by muse, mutect2, varscan2
- ASH2L | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1342895894, COSV51698982; called by muse, mutect2
- ASNSD1 | c.1115A>C p.N372T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs750799341, COSV99640965; called by mutect2, varscan2
- ASPA | c.596T>G p.I199S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99559122; called by muse, mutect2, varscan2
- ASPM | c.5537C>A p.S1846Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.746); catalogued as rs1334242199, COSV54125325, COSV99659410; called by muse, mutect2, varscan2
- ASTN1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs760442147, COSV56061330; called by muse, mutect2, varscan2
- ASXL2 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs781524282, COSV55455671; called by muse, mutect2, varscan2
- ASXL2 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 26/36 reads (72%) | catalogued as COSV55453991, COSV55459868; called by muse, mutect2, varscan2
- ASZ1 | c.1260A>C p.K420N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99497720; called by muse, mutect2, varscan2
- ATAD2B | c.3350G>T p.R1117I | Missense Mutation (SNP) | VAF 89/444 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.211); catalogued as COSV99476886; called by muse, mutect2, varscan2
- ATAT1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV99527673; called by muse, mutect2, varscan2
- ATG5 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV100576377; called by muse, mutect2, varscan2
- ATG5 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100576378; called by muse, mutect2, varscan2
- ATM | c.2464T>G p.L822V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as CD961797, COSV99587039; called by muse, mutect2, varscan2
- ATP10D | c.1110T>G p.F370L | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV99905077; called by muse, mutect2
- ATP11A | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs766879340, COSV52126969, COSV52127931; called by muse, mutect2, varscan2
- ATP11C | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 49/87 reads (56%) | catalogued as COSV100557258; called by muse, mutect2, varscan2
- ATP12A | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99516917; called by muse, mutect2, varscan2
- ATP12A | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768185894, COSV99516920; called by muse, mutect2, varscan2
- ATP13A5 | c.2254G>T p.E752* | Nonsense Mutation (SNP) | VAF 36/85 reads (42%) | catalogued as rs1352082779, COSV60866463; called by muse, mutect2, varscan2
- ATP13A5 | c.1675-1G>A p.X559_splice | Splice Site (SNP) | VAF 63/215 reads (29%) | catalogued as COSV100664814, COSV60869073; called by muse, mutect2, varscan2
- ATP1B4 | c.1066G>T p.E356* (on ENST00000218008 / NM_001142447.3; = p.E352* on NM_012069.5) | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99486105; called by muse, mutect2, varscan2
- ATP2A2 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as CM132883, COSV58046094; called by muse, mutect2, varscan2
- ATP2C1 | c.2710A>C p.K904Q | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100146209; called by muse, mutect2, varscan2
- ATP4A | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV52865717; called by muse, mutect2, varscan2
- ATP5F1B | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs777770019, COSV51637444; called by mutect2, varscan2
- ATP5MF | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99461547; called by muse, mutect2, varscan2
- ATP6V0D2 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV53416446; called by muse, mutect2, varscan2
- ATP6V1A | c.1632G>A p.M544I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99849788; called by muse, mutect2, varscan2
- ATP6V1C1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs772801674, COSV101214809; called by muse, mutect2, varscan2
- ATP8B4 | c.1344C>A p.F448L | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99463360; called by muse, varscan2
- ATP9A | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 153/587 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs781681734, COSV100124247; called by muse, varscan2
- ATR | c.4940G>A p.R1647H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs758322712, COSV63383741; called by muse, mutect2, varscan2
- ATR | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs564283952, COSV63385583, COSV63386951; called by muse, mutect2, varscan2
- ATRN | c.4115T>G p.F1372C | Missense Mutation (SNP) | VAF 116/437 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99496478; called by muse, mutect2
- ATRNL1 | c.3746C>T p.A1249V | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100369186; called by muse, mutect2, varscan2
- ATRX | c.4749G>T p.K1583N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV64885610; called by muse, varscan2
- ATRX | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64877356; called by muse, mutect2, varscan2
- ATRX | c.1162A>C p.K388Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV64885620; called by muse, mutect2, varscan2
- AUH | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs141700491; called by muse, mutect2, varscan2
- AURKC | c.408G>T p.E136D (on ENST00000302804 / NM_001015878.2; = p.E102D on NM_003160.3) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100248693; called by muse, mutect2, varscan2
- AXL | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781434711, COSV99995805; called by muse, mutect2, varscan2
- AXL | c.2120G>A p.R707H (on ENST00000301178 / NM_021913.5; = p.R698H on NM_001699.6) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs773403341, COSV99995808; called by muse, mutect2, varscan2
- AZIN1 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100457317; called by muse, mutect2, varscan2
- B3GLCT | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100587083; called by muse, mutect2, varscan2
- B3GLCT | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58454166; called by muse, mutect2, varscan2
- B3GNT5 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV58475736; called by muse, mutect2, varscan2
- B4GALT6 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV52702410; called by muse, mutect2
- BACH1 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV99727883; called by muse, mutect2, varscan2
- BAG4 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as COSV54860611; called by muse, mutect2, varscan2
- BAHD1 | c.2088G>T p.Q696H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101346709; called by muse, mutect2, varscan2
- BAIAP2L1 | c.70A>G p.N24D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99133603; called by muse, mutect2, varscan2
- BANK1 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as COSV100535789; called by muse, mutect2
- BANK1 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100535790; called by muse, mutect2, varscan2
- BATF2 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100101670; called by muse, mutect2, varscan2
- BBS9 | c.2330C>T p.S777F (on ENST00000242067 / NM_001348036.1; = p.S737F on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99625690; called by muse, mutect2, varscan2
- BCAS1 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV101006005; called by muse, mutect2, varscan2
- BCAS3 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101175018; called by muse, mutect2, varscan2
- BCAS3 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1184319232, COSV66772554; called by muse, mutect2
- BCCIP | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99532851; called by muse, mutect2, varscan2
- BCDIN3D | c.458T>G p.F153C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV100445432; called by muse, mutect2, varscan2
- BCHE | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100012047; called by muse, mutect2, varscan2
- BCL9 | c.2979T>G p.Y993* | Nonsense Mutation (SNP) | VAF 23/128 reads (18%) | catalogued as COSV99324393; called by muse, mutect2, varscan2
- BEST3 | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745673258, COSV58299229, COSV58299561; called by muse, mutect2, varscan2
- BHLHE41 | c.55T>G p.F19V | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV54378479; called by muse, mutect2
- BHMT2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs141648685, COSV54874678; called by muse, mutect2, varscan2
- BICDL1 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101287131; called by muse, mutect2, varscan2
- BIRC6 | c.14548G>T p.E4850* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV70202505; called by muse, mutect2, varscan2
- BLM | c.3755C>T p.S1252F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100756882, COSV61923990; called by muse, mutect2, varscan2
- BMP10 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV99770254; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, mutect2, varscan2
- BMP7 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101215390; called by muse, mutect2, varscan2
- BMPER | c.1421C>A p.S474Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV99778780; called by muse, mutect2, varscan2
- BMPER | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99778783; called by muse, mutect2, varscan2
- BMS1 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100996430; called by muse, varscan2
- BMS1 | c.1673G>T p.S558I | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.054); catalogued as rs1284854699, COSV100996432; called by muse, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 4/67 reads (6%) | catalogued as COSV51775023; called by muse, mutect2
- BNC1 | c.2339G>A p.S780N | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100596875; called by muse, mutect2, varscan2
- BNC1 | c.929C>G p.A310G | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100596877; called by muse, mutect2, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BPIFB4 | c.1095C>A p.F365L | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV100971403; called by muse, mutect2
- BPIFB6 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs750762957, COSV100848475; called by muse, mutect2, varscan2
- BPTF | c.8161C>T p.R2721C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100073904; called by muse, mutect2, varscan2
- BRD1 | c.3037G>A p.E1013K (on ENST00000216267 / NM_001349940.1; = p.E1144K on NM_001304808.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1046139158, COSV53462584; called by muse, mutect2, varscan2
- BRDT | c.1058C>A p.P353H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62865240; called by muse, mutect2
- BRINP3 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV66513604, COSV66513646; called by muse, mutect2, varscan2
- BRIP1 | c.3386C>A p.S1129Y | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99369113, COSV99371073; called by muse, mutect2, varscan2
- BRIP1 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs375082407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRSK1 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV100510259; called by muse, mutect2, varscan2
- BRSK1 | c.1044G>T p.K348N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100473606; called by muse, mutect2, varscan2
- BRWD1 | c.4852C>A p.L1618I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100312693; called by muse, mutect2, varscan2
- BSN | c.8497G>A p.A2833T | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56531162; called by muse, mutect2
- BTAF1 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs992826231, COSV99794822; called by muse, mutect2, varscan2
- BTAF1 | c.4391G>A p.R1464Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs966281593, COSV56429578; called by muse, varscan2
- BTBD10 | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99533298; called by muse, mutect2
- BTBD11 | c.3109C>A p.L1037I (on ENST00000280758 / NM_001018072.2; = p.L574I on NM_001017523.2) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.978); catalogued as COSV55022832; called by muse, mutect2
- BTBD7 | c.1648C>A p.L550I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.19); catalogued as COSV100597437; called by mutect2, varscan2
- BTK | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs782338603, COSV58117157; ClinVar: uncertain significance; called by muse, mutect2
- BTRC | c.824T>G p.I275S (on ENST00000370187 / NM_033637.4; = p.I239S on NM_003939.5) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927696; called by muse, mutect2, varscan2
- C12orf42 | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV59386810; called by muse, varscan2
- C12orf54 | c.207C>A p.C69* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100011496; called by muse, mutect2, varscan2
- C14orf39 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.319); catalogued as COSV100407194, COSV58780117; called by muse, mutect2, varscan2
- C16orf71 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs144417396, COSV54794707; called by muse, mutect2, varscan2
- C1orf112 | c.843A>G p.I281M | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV99609331; called by muse, mutect2, varscan2
- C1orf127 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV65439578; called by muse, mutect2, varscan2
- C1orf158 | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99847163; called by muse, mutect2
- C20orf194 | c.1712T>G p.F571C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99330189; called by muse, mutect2, varscan2
- C20orf194 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99330190; called by muse, mutect2, varscan2
- C20orf194 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 62/136 reads (46%) | catalogued as COSV52699229; called by muse, mutect2, varscan2
- C21orf62 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs148054755, COSV66672227; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2orf80 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as rs751832381; called by mutect2, varscan2
- C3orf20 | c.2330C>A p.S777Y | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99513315; called by muse, mutect2, varscan2
- C3orf33 | c.871C>T p.R291C (on ENST00000340171 / NM_001308229.2; = p.R248C on NM_173657.2) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs200965203; called by muse, mutect2, varscan2
- C6orf58 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV100314661; called by muse, mutect2, varscan2
- C6orf89 | c.619G>T p.E207* (on ENST00000373685; = p.E214* on NM_152734.4) | Nonsense Mutation (SNP) | VAF 82/122 reads (67%) | catalogued as COSV100769662; called by muse, varscan2
- C7orf25 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100623592; called by muse, mutect2, varscan2
- CACHD1 | c.2312C>A p.S771Y | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99261328; called by muse, mutect2, varscan2
- CACNA1E | c.5810C>T p.S1937L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1007685928, COSV62383196; called by muse, mutect2
- CACNA1G | c.4915C>A p.L1639M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61742101; called by muse, mutect2, varscan2
- CACNA1S | c.1450T>C p.Y484H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100754597; called by muse, mutect2, varscan2
- CACNA2D3 | c.1846T>G p.L616V | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99869741; called by muse, mutect2, varscan2
- CACNA2D4 | c.1823T>G p.I608S | Missense Mutation (SNP) | VAF 141/398 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV54963620; called by muse, mutect2, varscan2
- CAD | c.3142C>T p.R1048C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372902996, COSV99254340; called by mutect2, varscan2
- CADPS2 | c.3736C>T p.R1246* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs1354028382, COSV57349948, COSV57350326; called by muse, mutect2, varscan2
- CADPS2 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs771969548, COSV100460567; called by mutect2, varscan2
- CADPS2 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100460571; called by muse, varscan2
- CALD1 | c.1494C>A p.F498L (on ENST00000361675 / NM_033138.4; = p.F243L on NM_004342.7) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100723983, COSV62649842; called by muse, mutect2, varscan2
- CALHM5 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.116); catalogued as rs539288012, COSV100635512; called by muse, mutect2, varscan2
- CALM1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV63662962, COSV63663711; called by muse, mutect2
- CAMSAP1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV56719922; called by muse, mutect2
- CAPN2 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs144592508; called by muse, mutect2, varscan2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CARD8 | c.982G>A p.E328K (on ENST00000651546 / NM_001184900.3; = p.E278K on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as rs758242862, COSV62872805; called by muse, mutect2, varscan2
- CARMIL1 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs763392762, COSV61520503; called by muse, mutect2, varscan2
- CARNMT1 | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100961620; called by muse, varscan2
- CARNMT1 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV65194572; called by muse, mutect2, varscan2
- CASC3 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99229440; called by muse, mutect2, varscan2
- CASP1 | c.804G>T p.K268N (on ENST00000436863 / NM_033292.4; = p.K247N on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs202211771, COSV100782707; called by muse, mutect2, varscan2
- CASP14 | c.598G>T p.G200* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99692884; called by muse, mutect2, varscan2
- CASP5 | c.860T>G p.L287R | Missense Mutation (SNP) | VAF 82/265 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV99507108; called by muse, mutect2, varscan2
- CASR | c.365C>A p.S122Y | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.959); catalogued as rs778201006, CM1310392, COSV56134103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASR | c.1232A>G p.Y411C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.854); catalogued as COSV99948401; called by muse, mutect2, varscan2
- CASR | c.1595C>T p.T532M (on ENST00000490131; = p.T609M on NM_000388.4) | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.897); catalogued as rs759904153, COSV99948403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAST | c.577G>T p.E193* (on ENST00000341926; = p.E276* on NM_001750.7 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100352128; called by muse, mutect2, varscan2
- CASTOR1 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV57577180; called by muse, mutect2, varscan2
- CATSPERB | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs768019574, COSV56434429; called by muse, mutect2, varscan2
- CAVIN3 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV58269730; called by muse, mutect2, varscan2
- CBFA2T2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs146788442; called by muse, mutect2, varscan2
- CBLB | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); catalogued as rs1001266989, COSV99912558; called by muse, mutect2
- CBX3 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1208793747, COSV61761621; called by muse, mutect2, varscan2
- CCDC110 | c.1921A>C p.K641Q | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100293627; called by muse, mutect2, varscan2
- CCDC137 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs1183118474; called by muse, mutect2, varscan2
- CCDC138 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs896059293, COSV54567061; called by muse, varscan2
- CCDC14 | c.2451G>T p.K817N (on ENST00000488653; = p.K769N on NM_022757.5) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV100112911, COSV59947443; called by muse, mutect2, varscan2
- CCDC14 | c.1082G>T p.R361I (on ENST00000488653; = p.R313I on NM_022757.5) | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.134); catalogued as rs377682889; called by muse, mutect2, varscan2
- CCDC141 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs1212530049, COSV55379281; called by muse, mutect2, varscan2
- CCDC144A | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100138284; called by muse, mutect2, varscan2
- CCDC144A | c.3158G>A p.R1053Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as rs199644397; called by muse, mutect2, varscan2
- CCDC146 | c.1521T>G p.I507M | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV99592080; called by muse, mutect2, varscan2
- CCDC158 | c.305A>C p.E102A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV101187137; called by muse, mutect2, varscan2
- CCDC171 | c.3514G>T p.D1172Y | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs896927475, COSV52655502; called by muse, mutect2
- CCDC178 | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as COSV100283122; called by muse, mutect2
- CCDC18 | c.1507G>T p.D503Y (on ENST00000343253 / NM_001306076.1; = p.D504Y on NM_206886.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58147381; called by muse, mutect2, varscan2
- CCDC180 | c.3047C>A p.S1016* | Nonsense Mutation (SNP) | VAF 37/169 reads (22%) | catalogued as COSV63832688; called by muse, mutect2, varscan2
- CCDC181 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV100890231; called by muse, mutect2, varscan2
- CCDC186 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.124); catalogued as COSV100990979; called by muse, mutect2, varscan2
- CCDC191 | c.467T>G p.F156C | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1031780972, COSV55672221; called by muse, mutect2, varscan2
- CCDC198 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 195/686 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53601250; called by muse, mutect2, varscan2
- CCDC28A | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100236236; called by muse, mutect2, varscan2
- CCDC34 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as rs772307472, COSV58727391; called by muse, mutect2, varscan2
- CCDC39 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.055); catalogued as COSV99866987; called by muse, mutect2, varscan2
- CCDC39 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as rs1282693527, COSV99866991; called by muse, mutect2, varscan2
- CCDC39 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369208682; called by muse, mutect2
- CCDC39 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56477668, COSV99867362; called by muse, mutect2, varscan2
- CCDC63 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV100370155; called by muse, mutect2, varscan2
- CCDC7 | c.3072C>A p.F1024L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV100177350; called by mutect2, varscan2
- CCDC73 | c.1438A>C p.N480H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); catalogued as COSV100066342; called by muse, mutect2
- CCDC8 | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100281849; called by muse, mutect2, varscan2
- CCDC80 | c.2455T>A p.L819I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as COSV99244179; called by muse, mutect2, varscan2
- CCDC83 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs553174518, COSV54700993, COSV54703567; called by muse, mutect2, varscan2
- CCDC88A | c.4051C>A p.L1351I | Missense Mutation (SNP) | VAF 93/442 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.719); catalogued as COSV99709694; called by muse, mutect2, varscan2
- CCDC88A | c.2760G>T p.Q920H | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99709697; called by muse, mutect2, varscan2
- CCL27 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.217); catalogued as COSV99426383; called by muse, mutect2, varscan2
- CCN6 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100036884, COSV57890769; called by muse, mutect2, varscan2
- CCND1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99919169; called by muse, varscan2
- CCNH | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as rs1282114823, COSV56926026; called by muse, mutect2, varscan2
- CCPG1 | c.2199C>A p.F733L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as rs776958605, COSV99379977; called by muse, mutect2, varscan2
- CCSER1 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV61420796; called by muse, mutect2, varscan2
- CCSER2 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV56501827; called by muse, mutect2, varscan2
- CCT8L2 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100742544; called by muse, mutect2, varscan2
- CCZ1B | c.725G>T p.R242I | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100367706, COSV57438014; called by muse, mutect2
- CD101 | c.1618A>C p.S540R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as COSV99869056; called by muse, mutect2
- CD109 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99752440; called by muse, mutect2, varscan2
- CD109 | c.1876T>C p.F626L | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99752449; called by muse, varscan2
- CD109 | c.3977T>C p.V1326A | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV99752451; called by muse, mutect2, varscan2
- CD163 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV63129992; called by muse, mutect2, varscan2
- CD163L1 | c.4218T>G p.N1406K | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.439); catalogued as COSV100549605; called by muse, mutect2
- CD163L1 | c.2270C>A p.S757Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.972); catalogued as COSV58022993; called by muse, mutect2, varscan2
- CD209 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV52659939; called by muse, mutect2, varscan2
- CD22 | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV99322779; called by muse, mutect2, varscan2
- CD300A | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV60410352; called by muse, mutect2, varscan2
- CD300C | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV100423162; called by muse, mutect2
- CD300E | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.186); catalogued as rs545591203, COSV60790732; called by muse, mutect2, varscan2
- CD46 | c.736T>A p.F246I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM165481, COSV59735665; called by muse, varscan2
- CD46 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522703; called by muse, varscan2
- CD69 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99945946; called by muse, mutect2
- CD72 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99427247; called by muse, mutect2
- CD84 | c.892G>T p.E298* (on ENST00000311224 / NM_001184879.2; = p.E281* on NM_003874.4) | Nonsense Mutation (SNP) | VAF 56/139 reads (40%) | catalogued as COSV100245777; called by muse, mutect2, varscan2
- CDC42BPA | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62003520; called by muse, mutect2, varscan2
- CDC42EP3 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99767745; called by muse, mutect2, varscan2
- CDC5L | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV65175963; called by muse, mutect2
- CDC7 | c.1533T>G p.N511K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as COSV99319520; called by muse, mutect2, varscan2
- CDCA7L | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100650944, COSV62261312; called by muse, mutect2, varscan2
- CDH10 | c.2249C>A p.S750* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as COSV52571640, COSV52585324; called by muse, mutect2, varscan2
- CDH10 | c.1294T>G p.F432V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100049904; called by muse, mutect2, varscan2
- CDH10 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV100049907, COSV100050786; called by muse, mutect2, varscan2
- CDH10 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.067); catalogued as COSV100049909; called by muse, varscan2
- CDH10 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049911; called by muse, mutect2, varscan2
- CDH11 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs201146780, COSV99217010; called by muse, varscan2
- CDH12 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV66387559; called by muse, mutect2, varscan2
- CDH18 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV56903914; called by muse, varscan2
- CDH19 | c.153dup p.V52Cfs*9 | Frame Shift Ins (INS) | VAF 20/75 reads (27%) | catalogued as rs746163720; called by mutect2, pindel, varscan2
- CDH2 | c.2304T>G p.D768E | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99295517; called by muse, mutect2, varscan2
- CDH2 | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52271407; called by muse, mutect2, varscan2
- CDH2 | c.1557C>A p.F519L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV99295519; called by muse, mutect2, varscan2
- CDH20 | c.1482C>A p.F494L | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV53016850, COSV99404208; called by muse, mutect2, varscan2
- CDH23 | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs746487992, COSV99818581; called by muse, mutect2, varscan2
- CDH23 | c.5143G>T p.D1715Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56463839, COSV99818587; called by muse, mutect2, varscan2
- CDH26 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs1479719725, COSV54847357; called by muse, mutect2, varscan2
- CDH6 | c.530T>G p.F177C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV99417931; called by muse, mutect2, varscan2
- CDH8 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 181/491 reads (37%) | catalogued as COSV100179393; called by muse, varscan2
- CDH9 | c.1569C>A p.F523L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50330527, COSV99141382; called by muse, mutect2, varscan2
- CDH9 | c.811+2T>C p.X271_splice | Splice Site (SNP) | VAF 70/221 reads (32%) | catalogued as COSV99141385; called by muse, mutect2, varscan2
- CDH9 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV99141391; called by muse, mutect2, varscan2
- CDHR1 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV100258346, COSV100259224; called by muse, mutect2, varscan2
- CDK13 | c.2520T>G p.C840W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99474990; called by muse, mutect2
- CDK4 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763652580, COSV56986143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3106G>A p.D1036N | Missense Mutation (SNP) | VAF 180/629 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV100575033; called by muse, mutect2, varscan2
- CDK7 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99841497; called by muse, mutect2, varscan2
- CDNF | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101012354; called by muse, mutect2, varscan2
- CDRT1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1327139893, COSV63052386, COSV63054528; called by muse, mutect2, varscan2
- CEACAM18 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101140125; called by muse, mutect2, varscan2
- CEACAM18 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs267605617; called by muse, mutect2, varscan2
- CEBPZ | c.2087A>G p.Y696C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99304945; called by muse, mutect2, varscan2
- CELA2B | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV65545914; called by muse, mutect2
- CELF3 | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.994); catalogued as COSV99309989; called by muse, mutect2, varscan2
- CEMIP | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs181470477, COSV99585950; called by muse, mutect2, varscan2
- CEMIP | c.2213T>C p.I738T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV99585953; called by muse, varscan2
- CENPE | c.7668T>G p.I2556M | Missense Mutation (SNP) | VAF 113/296 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV54380847; called by muse, mutect2, varscan2
- CENPE | c.2356C>A p.H786N | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV99476853; called by muse, mutect2, varscan2
- CENPF | c.4227G>T p.E1409D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV65273638; called by muse, mutect2, varscan2
- CENPF | c.8124G>T p.K2708N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV100871470, COSV65278286; called by muse, mutect2, varscan2
- CEP112 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs549226002, COSV101210480; called by muse, mutect2, varscan2
- CEP128 | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99823522; called by muse, mutect2
- CEP128 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as rs573572660, COSV55383907; called by muse, mutect2, varscan2
- CEP152 | c.4576G>A p.D1526N (on ENST00000380950 / NM_001194998.2; = p.D1470N on NM_014985.4) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.103); catalogued as rs577236018, COSV57856542; called by muse, mutect2, varscan2
- CEP152 | c.2960G>A p.R987Q | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755071182, COSV57858956; called by muse, mutect2, varscan2
- CEP152 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 12/302 reads (4%) | catalogued as COSV57858240; called by muse, mutect2
- CEP192 | c.7174G>A p.E2392K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1298184979, COSV100380507; called by muse, mutect2, varscan2
- CEP290 | c.4990G>T p.E1664* | Nonsense Mutation (SNP) | VAF 42/141 reads (30%) | catalogued as COSV100467681; called by muse, mutect2, varscan2
- CEP350 | c.4608G>T p.K1536N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV62610727; called by muse, mutect2
- CEP70 | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 100/393 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV99388775; called by muse, mutect2, varscan2
- CEP83 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 124/613 reads (20%) | catalogued as rs1216945458, COSV60407553; called by muse, varscan2
- CEP83 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 83/262 reads (32%) | catalogued as COSV60407666, COSV60408122; called by muse, mutect2, varscan2
- CEP85L | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as rs752640404, COSV100874025; called by muse, mutect2, varscan2
- CEP95 | c.1988T>A p.I663N | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV73609713; called by muse, mutect2, varscan2
- CERKL | c.815G>T p.R272I (on ENST00000339098 / NM_001030311.2; = p.R246I on NM_201548.5) | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100183067, COSV59206395; called by muse, mutect2, varscan2
- CERS3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752230253, COSV52567747; called by muse, mutect2, varscan2
- CES5A | c.1520C>A p.S507Y (on ENST00000290567 / NM_001143685.2; = p.S457Y on NM_145024.3) | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV51865594, COSV99307047; called by muse, mutect2, varscan2
- CFAP161 | c.711-1G>T p.X237_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99715355; called by muse, mutect2, varscan2
- CFAP206 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.131); catalogued as rs777448285, COSV51534027; called by mutect2, varscan2
- CFAP251 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99995665; called by muse, mutect2, varscan2
- CFAP46 | c.6493C>T p.P2165S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs560086678, COSV99583847; called by mutect2, varscan2
- CFAP47 | c.4439A>C p.E1480A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.486); catalogued as COSV100544856; called by muse, mutect2, varscan2
- CFAP54 | c.5119G>T p.E1707* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV61570456, COSV61570908; called by muse, mutect2, varscan2
- CFAP54 | c.7023G>T p.K2341N | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.854); catalogued as COSV61572445; called by muse, mutect2, varscan2
- CFAP58 | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as rs61732088; called by muse, mutect2, varscan2
- CFAP94 | c.1988C>A p.S663Y (on ENST00000320267 / NM_001352064.2; = p.S669Y on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100208869; called by muse, varscan2
- CFAP94 | c.1908G>T p.E636D (on ENST00000320267 / NM_001352064.2; = p.E642D on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100208870; called by muse, varscan2
- CFHR4 | c.171A>C p.Q57H (on ENST00000367416 / NM_001201551.2; = p.Q58H on NM_006684.5) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); catalogued as COSV52228686; called by muse, mutect2
- CFLAR | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100009049; called by muse, mutect2, varscan2
- CFTR | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769476932, COSV50107466, COSV99133859, COSV99139792; called by muse, mutect2, varscan2
- CGN | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751915500, COSV54969464, COSV99641828; called by mutect2, varscan2
- CGNL1 | c.2114A>C p.D705A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV99847351; called by muse, mutect2, varscan2
- CHAF1A | c.1731G>T p.K577N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV100010771; called by muse, mutect2, varscan2
- CHAF1B | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs759420528, COSV100023316; called by muse, mutect2, varscan2
- CHCHD6 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV99335591; called by muse, mutect2, varscan2
- CHD1 | c.4832G>T p.R1611M | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV99399040; called by muse, mutect2
- CHD1 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV52336710; called by muse, mutect2, varscan2
- CHD4 | c.3241G>A p.E1081K (on ENST00000357008 / NM_001363606.2; = p.E1094K on NM_001273.5) | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58894162; called by muse, mutect2, varscan2
- CHD5 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV99312266; called by muse, mutect2, varscan2
- CHD7 | c.3535C>A p.Q1179K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as CM074742, COSV101417964; called by muse, mutect2, varscan2
- CHD9 | c.2046G>A p.E682= | Splice Region (SNP) | VAF 20/46 reads (43%) | catalogued as COSV101271848, COSV68297875; called by muse, mutect2, varscan2
- CHD9 | c.5670C>A p.F1890L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99528653; called by muse, mutect2, varscan2
- CHD9 | c.7367C>A p.S2456Y (on ENST00000398510 / NM_001382353.1; = p.S2440Y on NM_025134.7) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99528654; called by muse, mutect2, varscan2
- CHD9 | c.8170C>A p.L2724M (on ENST00000398510 / NM_001382353.1; = p.L2708M on NM_025134.7) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.986); catalogued as COSV54613377; called by muse, mutect2
- CHERP | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52225429, COSV99550585; called by muse, mutect2, varscan2
- CHIA | c.1390C>T p.L464F (on ENST00000343320; = p.L356F on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58478978; called by muse, mutect2, varscan2
- CHL1 | c.757C>A p.L253I (on ENST00000397491 / NM_001253387.1; = p.L269I on NM_006614.4) | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.495); catalogued as COSV99849938; called by muse, mutect2, varscan2
- CHL1 | c.3160G>A p.D1054N (on ENST00000397491 / NM_001253387.1; = p.D1070N on NM_006614.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs752896455, COSV56589298; called by muse, mutect2, varscan2
- CHL1 | c.3343G>A p.E1115K (on ENST00000397491 / NM_001253387.1; = p.E1131K on NM_006614.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56602684, COSV56609582; called by muse, mutect2, varscan2
- CHML | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59363937; called by muse, mutect2, varscan2
- CHMP3 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV55686043; called by muse, varscan2
- CHMP3 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV55684997, COSV99806494; called by muse, mutect2
- CHMP7 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as rs149875498; called by muse, mutect2, varscan2
- CHODL | c.611A>C p.Q204P | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV100166564; called by muse, mutect2, varscan2
- CHRAC1 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV99636066; called by muse, varscan2
- CHRM2 | c.959C>A p.S320Y | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100280647, COSV57768376, COSV57782619; called by muse, mutect2, varscan2
- CHRNA2 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV99531859; called by muse, mutect2, varscan2
- CHRNB1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV99548141; called by muse, mutect2, varscan2
- CHRNB2 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100872525, COSV63808275, COSV63808363; called by muse, mutect2, varscan2
- CHRNB3 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.946); catalogued as COSV99250835; called by muse, mutect2, varscan2
- CHST10 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as rs764927277, COSV51804914; called by muse, mutect2, varscan2
- CHST15 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753436566, COSV60560851; called by muse, mutect2, varscan2
- CHST15 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100654899, COSV60565823; called by muse, mutect2, varscan2
- CHST9 | c.977C>A p.S326Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52450231, COSV52451894; called by muse, mutect2, varscan2
- CHSY3 | c.1857G>T p.K619N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs1297392868, COSV100518401, COSV59276872; called by muse, mutect2, varscan2
- CHSY3 | c.2095C>T p.L699F | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV100518402; called by muse, mutect2, varscan2
- CIBAR1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100844624; called by muse, mutect2
- CITED2 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100863091; called by muse, mutect2, varscan2
- CKAP5 | c.271T>C p.S91P | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV100370329; called by muse, mutect2, varscan2
- CKS1B | c.15A>C p.Q5H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100460337; called by muse, mutect2, varscan2
- CLASP1 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV55332299; called by muse, mutect2, varscan2
- CLCC1 | c.1027G>T p.A343S (on ENST00000356970 / NM_001377464.1; = p.A293S on NM_015127.5) | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100206188; called by muse, mutect2
- CLCN1 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 27/135 reads (20%) | catalogued as CM110546, COSV58369685, COSV58369998; called by muse, mutect2, varscan2
- CLCN3 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.125); catalogued as COSV100641567; called by muse, mutect2, varscan2
- CLDN7 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100598030; called by muse, mutect2, varscan2
- CLDND2 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV99389786; called by muse, mutect2, varscan2
- CLEC10A | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99644518; called by muse, mutect2, varscan2
- CLEC1A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs779048525, COSV100191095; called by muse, mutect2, varscan2
- CLEC4E | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV55225062; called by muse, mutect2, varscan2
- CLEC7A | c.634A>G p.T212A (on ENST00000304084 / NM_197947.3; = p.T166A on NM_022570.5) | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100045554; called by muse, varscan2
- CLIC6 | c.1489C>A p.L497I (on ENST00000360731 / NM_001317009.2; = p.L479I on NM_053277.3) | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100659105, COSV62449329; called by muse, mutect2, varscan2
- CLIP1 | c.3750G>T p.E1250D (on ENST00000620786 / NM_001247997.1; = p.E1239D on NM_002956.2) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV100211126; called by muse, mutect2, varscan2
- CLIP4 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100191387; called by muse, mutect2, varscan2
- CLIP4 | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV100191392; called by muse, mutect2, varscan2
- CLK1 | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100362106; called by muse, mutect2, varscan2
- CLNK | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 122/498 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57023865; called by muse, varscan2
- CLNS1A | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as rs373008022; called by mutect2, varscan2
- CLOCK | c.2355T>G p.F785L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100011544, COSV59403818; called by muse, mutect2, varscan2
- CLOCK | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV59400616; called by muse, mutect2, varscan2
- CLSTN1 | c.1540G>T p.D514Y (on ENST00000377298 / NM_001009566.3; = p.D504Y on NM_014944.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100790445; called by muse, mutect2
- CLTCL1 | c.2833C>T p.R945C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs781816059, COSV99594469, COSV99595985; called by muse, mutect2, varscan2
- CLUAP1 | c.664T>G p.L222V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.068); catalogued as COSV100489459; called by muse, mutect2, varscan2
- CMTM5 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100197901; called by muse, mutect2
- CMTM5 | c.490C>T p.R164C (on ENST00000339180 / NM_001288746.2; = p.R97C on NM_138460.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs745646073, COSV100197904; called by mutect2, varscan2
- CMYA5 | c.11210C>A p.S3737* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV71409401, COSV71410368; called by muse, mutect2, varscan2
- CNGA3 | c.1558T>C p.Y520H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99735970; called by muse, mutect2, varscan2
- CNGB1 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV51903682; called by muse, mutect2
- CNGB3 | c.1455T>G p.Y485* | Nonsense Mutation (SNP) | VAF 82/202 reads (41%) | catalogued as COSV100181099; called by muse, varscan2
- CNN1 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52957206; called by mutect2, varscan2
- CNOT1 | c.6035A>C p.N2012T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV99799173; called by muse, mutect2, varscan2
- CNOT1 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57782419; called by muse, mutect2, varscan2
- CNOT1 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 70/331 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV57773806, COSV57782446; called by muse, mutect2, varscan2
- CNTLN | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV52101364; called by muse, varscan2
- CNTLN | c.644T>G p.F215C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV52101372; called by muse, varscan2
- CNTN3 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as rs1411446522, COSV99723116; called by muse, mutect2, varscan2
- CNTN3 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99723119; called by muse, mutect2, varscan2
- CNTN4 | c.501T>G p.D167E | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100638774; called by muse, mutect2, varscan2
- CNTN5 | c.2673G>T p.E891D | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV99672377, COSV99674766; called by muse, mutect2, varscan2
- CNTNAP4 | c.2651A>G p.N884S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs1169212925, COSV56705150; called by muse, varscan2
- CNTNAP5 | c.977T>A p.F326Y | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101442992; called by muse, varscan2
- CNTNAP5 | c.2431T>G p.F811V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV101442993; called by muse, mutect2, varscan2
- COBLL1 | c.2786T>G p.F929C (on ENST00000392717; = p.F891C on NM_014900.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.439); catalogued as rs1209198625, COSV99527272; called by muse, mutect2, varscan2
- COG3 | c.625-1G>T p.X209_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV63071148; called by muse, mutect2, varscan2
- COL11A1 | c.5053G>T p.D1685Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62173972; called by mutect2, varscan2
- COL11A1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV100618280, COSV62201699; called by muse, mutect2, varscan2
- COL12A1 | c.6493G>T p.E2165* | Nonsense Mutation (SNP) | VAF 77/224 reads (34%) | catalogued as COSV100485303; called by muse, mutect2, varscan2
- COL12A1 | c.4378G>T p.D1460Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100485304; called by muse, mutect2, varscan2
- COL13A1 | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 152/406 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100637238; called by mutect2, varscan2
- COL14A1 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs201867541, COSV52850957; called by muse, mutect2, varscan2
- COL14A1 | c.4892A>G p.H1631R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs780491267, COSV99917821; called by muse, mutect2, varscan2
- COL16A1 | c.3150C>T p.I1050= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as rs368007133, COSV54705941; called by muse, mutect2, varscan2
- COL1A2 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745988180, COSV99798421; called by muse, mutect2, varscan2
- COL21A1 | c.2380C>T p.R794* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs377112827, COSV55159886; called by muse, mutect2, varscan2
- COL22A1 | c.4723G>T p.D1575Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100276078, COSV57360260; called by muse, mutect2, varscan2
- COL24A1 | c.2777G>T p.R926I | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100992831; called by muse, mutect2
- COL24A1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs200728036, COSV65307350; called by muse, mutect2, varscan2
- COL4A1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV65431936; called by muse, mutect2, varscan2
- COL4A3 | c.1580T>C p.F527S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as COSV101169851; called by mutect2, varscan2
- COL4A3 | c.4660C>T p.P1554S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV101169853; called by muse, mutect2, varscan2
- COL4A5 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 60/102 reads (59%) | catalogued as COSV100086348; called by muse, varscan2
- COL5A2 | c.2604G>T p.Q868H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV100879973; called by muse, mutect2, varscan2
- COL5A2 | c.142T>C p.Y48H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs750126490, COSV100879975; called by muse, mutect2, varscan2
- COL6A3 | c.8374G>A p.D2792N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746208987, COSV55084775; called by muse, mutect2, varscan2
- COL6A3 | c.3331G>A p.A1111T | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs151021451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs767499336, COSV99796082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.5356G>A p.D1786N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100649734; called by muse, mutect2, varscan2
- COL9A1 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100293943; called by muse, mutect2, varscan2
- COL9A1 | c.981A>C p.L327F | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV100293948; called by muse, mutect2, varscan2
- COLEC12 | c.1143T>G p.D381E | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101231938; called by muse, mutect2, varscan2
- COPB1 | c.1540T>G p.L514V | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.088); catalogued as COSV99999231; called by muse, mutect2, varscan2
- COPB2 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1560022040, COSV100300435, COSV60811728; called by muse, mutect2, varscan2
- COPRS | c.335T>A p.F112Y | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.544); catalogued as COSV100188326; called by muse, mutect2, varscan2
- COPS6 | c.472A>C p.T158P | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100384554; called by muse, mutect2
- COQ10B | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs776608625, COSV55836205; called by muse, mutect2, varscan2
- COX6C | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV99881838; called by muse, mutect2, varscan2
- CP | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223665; called by muse, mutect2, varscan2
- CPAMD8 | c.2578G>A p.A860T (on ENST00000651564; = p.A813T on NM_015692.5) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs756903738, COSV101488380; called by mutect2, varscan2
- CPD | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99852386; called by muse, mutect2
- CPEB1 | c.1135C>T p.P379S (on ENST00000617958; = p.P319S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99917371; called by muse, mutect2, varscan2
- CPS1 | c.2667G>T p.K889N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99241953; called by muse, mutect2
- CPXM1 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 126/347 reads (36%) | catalogued as rs201037077, COSV101013668; called by muse, mutect2, varscan2
- CR1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV65461593; called by muse, mutect2, varscan2
- CR2 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100889515; called by muse, mutect2, varscan2
- CR2 | c.1187A>G p.Q396R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.881); catalogued as COSV100889517; called by muse, mutect2, varscan2
- CRB1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as COSV100958295; called by muse, mutect2, varscan2
- CRB1 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100958296, COSV66344110; called by muse, mutect2, varscan2
- CRB1 | c.3076T>G p.L1026V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100957639; called by muse, mutect2, varscan2
- CRBN | c.707A>C p.N236T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV99214025; called by muse, mutect2, varscan2
- CRHR2 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV59263932; called by muse, mutect2, varscan2
- CRX | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs370592248; called by muse, mutect2, varscan2
- CSF1R | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV99640724; called by muse, mutect2, varscan2
- CSMD1 | c.8487G>T p.K2829N (on ENST00000520002; = p.K2828N on NM_033225.6) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.994); catalogued as COSV100142976, COSV100152045; called by muse, mutect2, varscan2
- CSMD1 | c.6401G>T p.R2134I (on ENST00000520002; = p.R2133I on NM_033225.6) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100142978; called by muse, mutect2, varscan2
- CSMD1 | c.4727G>T p.R1576I (on ENST00000520002; = p.R1575I on NM_033225.6) | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs761063399, COSV100142993; called by muse, varscan2
- CSMD1 | c.2345C>A p.S782Y (on ENST00000520002; = p.S781Y on NM_033225.6) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs766601526, COSV59294145; called by muse, varscan2
- CSMD1 | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101212960; called by muse, mutect2, varscan2
- CSMD2 | c.5660A>G p.Y1887C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV99585428; called by muse, mutect2, varscan2
- CSMD3 | c.2047C>T p.R683C (on ENST00000297405 / NM_001363185.1; = p.R579C on NM_052900.3) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1266203286, COSV52185681; called by muse, mutect2, varscan2
- CSNK1A1L | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as COSV65789520; called by muse, mutect2, varscan2
- CSPP1 | c.2320G>T p.E774* (on ENST00000676605; = p.E733* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99137981; called by muse, mutect2, varscan2
- CSRNP1 | c.1368G>T p.E456D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); catalogued as COSV99826673; called by muse, mutect2, varscan2
- CSRNP3 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as rs774567924, COSV100086475, COSV58787933; called by muse, mutect2, varscan2
- CTAGE1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV66945339; called by muse, mutect2, varscan2
- CTCFL | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 142/268 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs765675257, COSV54773669; called by muse, varscan2
- CTHRC1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767759004, COSV100372900; called by muse, mutect2, varscan2
- CTNNA2 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100559375, COSV58144333; called by muse, mutect2, varscan2
- CTNNA2 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV58136714, COSV58173769; called by muse, mutect2, varscan2
- CTNNA3 | c.1766C>G p.A589G | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101045581; called by muse, mutect2, varscan2
- CTNND2 | c.2800A>G p.M934V | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV100471218; called by muse, mutect2, varscan2
- CUBN | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100912010, COSV100913379; called by muse, mutect2, varscan2
- CUL4B | c.2488G>T p.E830* | Nonsense Mutation (SNP) | VAF 84/110 reads (76%) | catalogued as COSV100340091; called by muse, mutect2, varscan2
- CUL9 | c.3041C>A p.S1014Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99334669; called by muse, mutect2, varscan2
- CWC15 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 130/576 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1555095301, COSV99688423; called by muse, varscan2
- CWC22 | c.1513A>C p.K505Q | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99843908; called by muse, mutect2
- CWC22 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99843910; called by muse, mutect2, varscan2
- CWF19L2 | c.1230G>T p.K410N | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56510118; called by muse, mutect2, varscan2
- CXorf58 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101002921; called by muse, mutect2, varscan2
- CYLC2 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs956648077, COSV66336380; called by muse, mutect2, varscan2
- CYLC2 | c.959A>C p.K320T | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100872347; called by muse, mutect2, varscan2
- CYP11A1 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99165881; called by muse, mutect2, varscan2
- CYP11B2 | c.1508A>C p.N503T | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs146765393; called by muse, mutect2, varscan2
- CYP1A2 | c.788T>G p.F263C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100673847; called by muse, mutect2, varscan2
- CYP27A1 | c.1238T>G p.V413G | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs587778783, CM121352, COSV99298313; called by muse, mutect2, varscan2
- CYP2C19 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 117/521 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs138112316, COSV64907487; called by muse, mutect2, varscan2
- CYP3A4 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60504759; called by muse, mutect2
- CYP3A5 | c.742T>G p.F248V | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99769452; called by muse, mutect2, varscan2
- CYP3A7 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100312530; called by muse, mutect2, varscan2
- CYP4B1 | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV54722940, COSV99596745; called by muse, mutect2, varscan2
- CYP51A1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs776540678, COSV50151372; called by muse, mutect2, varscan2
- CYP51A1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 41/123 reads (33%) | catalogued as COSV99133562; called by muse, mutect2, varscan2
- CYP7A1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1391016723, COSV56963072; called by muse, mutect2
- CYTIP | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.018); catalogued as rs1168235702, COSV99938616; called by muse, mutect2, varscan2
- DAAM1 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100658095; called by muse, mutect2
- DAB2 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as COSV100297757, COSV57913556; called by muse, mutect2, varscan2
- DACH2 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100912428; called by muse, varscan2
- DAPK1 | c.461A>C p.K154T | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as rs758563684, COSV100800878; called by muse, mutect2, varscan2
- DCAF12L2 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63583212, COSV63584206; called by muse, varscan2
- DCAF13 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs761547809, COSV52571384; called by muse, mutect2, varscan2
- DCAF4L2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV60481465, COSV60482929, COSV99081978; called by muse, mutect2, varscan2
- DCAF6 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100393820, COSV56576961; called by muse, varscan2
- DCAF8 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100470101; called by muse, mutect2, varscan2
- DCAF8 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100470105; called by muse, mutect2, varscan2
- DCBLD1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs1345084436, COSV99757006; called by muse, mutect2, varscan2
- DCDC2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99219658; called by muse, mutect2, varscan2
- DCLRE1A | c.3091T>G p.F1031V | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV100800190; called by muse, mutect2, varscan2
- DCLRE1B | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1406000401, COSV100849762; called by muse, mutect2, varscan2
- DCP1A | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs1553692605, COSV99587773; called by muse, mutect2, varscan2
- DCUN1D2 | c.470T>G p.F157C | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100215058; called by muse, mutect2, varscan2
- DCX | c.1099T>C p.*367Qext*48 (on ENST00000636035 / NM_001195553.2; = p.*361Qext*48 on NM_000555.3) | Nonstop Mutation (SNP) | VAF 78/128 reads (61%) | catalogued as COSV100576160; called by muse, varscan2
- DDA1 | c.85-1G>T p.X29_splice | Splice Site (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100724733; called by muse, mutect2, varscan2
- DDAH1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 15/184 reads (8%) | catalogued as COSV99394543; called by muse, mutect2
- DDI1 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100157651; called by muse, mutect2, varscan2
- DDR2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as rs745687175, COSV100906158; called by muse, mutect2, varscan2
- DDR2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100906159; called by muse, mutect2, varscan2
- DDX18 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs778782995, COSV54306284; called by muse, mutect2, varscan2
- DDX20 | c.1821G>T p.E607D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV100861960; called by muse, mutect2, varscan2
- DDX42 | c.2128C>A p.H710N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100834822; called by muse, mutect2, varscan2
- DDX47 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774098537, COSV100774469; called by muse, mutect2, varscan2
- DDX60 | c.2183A>C p.K728T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV101190220; called by muse, mutect2, varscan2
- DENND11 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as rs758501488, COSV101530690, COSV101530702; called by muse, mutect2, varscan2
- DENND1B | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99343681; called by muse, varscan2
- DENND2B | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100567087; called by muse, mutect2, varscan2
- DENND2D | c.559T>C p.F187L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100718507; called by muse, mutect2, varscan2
- DENND6A | c.1581A>C p.Q527H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV60767749; called by muse, mutect2, varscan2
- DEPDC4 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as COSV54553166; called by muse, mutect2, varscan2
3,166 further variants in this file (2,364 protein-altering or splice-affecting, 721 silent, 81 other) are not listed here.
